Surgical pathology report (de-identified scan), TCGA case TCGA-26-5132, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-5132-01A (Primary Tumor).

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Brain tumor [REDACTED] A. Frozen Section Charge ([REDACTED])

CLINICAL HISTORY: [REDACTED] with brain mass, new with
[REDACTED] here today for right craniotomy, history
of prostate cancer.

GROSS DESCRIPTION: Received the following specimen in the Department of
Pathology, labeled with the patient's name and hospital:

A. Brain tumor

A. The specimen is received fresh, labeled "brain tumor," and consists
of a 3.5 x 3.2 x 2.5 cm portion of tan soft tissue. A representative
portion is submitted for frozen section and touch prep. Frozen section
diagnosis is, "Malignant glioma, glioblastoma." By [REDACTED] The
frozen section tissue is submitted entirely for permanent processing in
cassette FSA1. The remaining tissue is submitted in cassettes FSA1 and
the remaining tissue is submitted in cassettes A2-A4. ([REDACTED])

DIAGNOSIS:

A. "Brain tumor":

Glioblastoma multiforme (WHO Grade IV astrocytoma)

"I, or my qualified designee, have performed the gross examination and
description and I have personally reviewed the gross description and
specimen preparations referenced herein, and have personally issued this
report."

Resident/Prosector/Pathologist: [REDACTED]

Note: Test systems have been developed and their performance
characteristics determined by [REDACTED] Some tests
have not been cleared or approved by the US Food and Drug Administration.
The FDA has determined that such clearance is not necessary. These tests
are used for clinical purposes and should not be regarded as
investigational or for research. This laboratory is certified under the
Clinical Laboratory Improvement Amendments of [REDACTED] as qualified
to perform high complexity clinical laboratory testing.

Pathologist

Electronically signed [REDACTED]

Source: NCI Genomic Data Commons file ef7045bb-1297-4255-9c62-978e12cd0692 (TCGA-26-5132.A2075373-4A3F-4F19-BC80-A46537C888DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).